Somatic mutation profile of tumor specimen TCGA-BR-8588-01A (aliquot TCGA-BR-8588-01A-11D-2394-08) from TCGA case TCGA-BR-8588, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,177 days).
Specimen TCGA-BR-8588-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc71d9c-116b-4a47-87f5-7385336a380a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8588-10A (Blood Derived Normal), aliquot TCGA-BR-8588-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aef38104-4a1d-4259-bc40-cad877d0e794

The open-access MAF lists 128 somatic variants for this specimen: 92 protein-altering or splice-affecting, 31 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 31, Nonsense Mutation 9, Frame Shift Del 5, RNA 2, Intron 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 67/275 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.331A>G p.K111E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs1057519933, COSV55878486, COSV56029794; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACVR1B | c.1358G>A p.R453H | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57775684; called by muse, mutect2, varscan2
- ADAM15 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV55128108; called by muse, mutect2
- ADAMTSL2 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | catalogued as rs778178248, COSV63205026; called by muse, mutect2, varscan2
- ADGRG4 | c.4937T>C p.L1646P | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54960729; called by muse, mutect2, varscan2
- ADGRV1 | c.12208G>A p.V4070I | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs200943280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHSG | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56608331; called by muse, mutect2
- ALAS2 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV58191767; called by muse, mutect2, varscan2
- ANOS1 | c.968T>C p.I323T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); catalogued as COSV99391651; called by muse, mutect2, varscan2
- AP002512.3 | c.66A>C p.Q22H | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56565891; called by muse, mutect2, varscan2
- ARHGEF37 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs768240553, COSV61369292; called by muse, mutect2, varscan2
- ARID2 | c.4328G>A p.S1443N | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.055); catalogued as COSV57608413; called by muse, mutect2, varscan2
- ATG16L1 | c.1364T>C p.I455T (on ENST00000392017 / NM_030803.7; = p.I436T on NM_017974.4) | Missense Mutation (SNP) | VAF 57/168 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV61466608; called by muse, mutect2, varscan2
- BMPR2 | c.642T>A p.Y214* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as CM1513943, COSV65810909; called by muse, mutect2, varscan2
- CCNT1 | c.1781G>A p.S594N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56064968; called by muse, mutect2, varscan2
- CDH9 | c.1165T>G p.L389V | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV50339154, COSV99145991; called by muse, mutect2, varscan2
- CEBPZ | c.2455A>T p.K819* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as rs757023726, COSV52207180; called by muse, mutect2
- CHST3 | c.586T>A p.F196I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV64151232; called by muse, mutect2
- CNTN6 | c.1329G>T p.W443C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63178343; called by muse, mutect2, varscan2
- CPXM2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs145723018; called by muse, mutect2, varscan2
- CRACD | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.077); catalogued as rs1456346118, COSV51725259; called by muse, mutect2, varscan2
- CREBRF | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV51634286; called by muse, mutect2, varscan2
- CSMD3 | c.1565A>G p.K522R (on ENST00000297405 / NM_001363185.1; = p.K418R on NM_052900.3) | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52231101; called by muse, mutect2, varscan2
- CTCF | c.1181T>C p.L394P | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50478767; called by muse, mutect2, varscan2
- CX3CL1 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs771801757, COSV50056292; called by muse, mutect2, varscan2
- DLG2 | c.165T>G p.F55L (on ENST00000650630 / NM_001351274.2; = p.F18L on NM_001142699.3) | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65821881, COSV65833079; called by muse, mutect2, varscan2
- DNASE2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.05); catalogued as COSV52249791; called by muse, mutect2, varscan2
- EPHA4 | c.2794T>G p.F932V | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV56037541; called by muse, mutect2, varscan2
- FAT2 | c.10592C>A p.A3531D | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV55823664; called by muse, mutect2, varscan2
- FEZF2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.018); catalogued as COSV51863356; called by muse, mutect2, varscan2
- FGF14 | c.8C>A p.A3E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.714); catalogued as COSV65947798; called by muse, mutect2, varscan2
- FLT4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs368167894; called by muse, mutect2, varscan2
- FRMPD4 | c.2689C>T p.R897W | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766899987, COSV66218280; called by muse, mutect2, varscan2
- GLI3 | c.2141G>T p.S714I | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67890777; called by muse, mutect2, varscan2
- GUCY1A2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV56492221; called by muse, mutect2
- HECW1 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 18/208 reads (9%) | catalogued as COSV67833792, COSV67839537; called by muse, mutect2
- HIVEP2 | c.4939G>A p.V1647M | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50016307; called by muse, mutect2, varscan2
- HMCN1 | c.12913G>T p.D4305Y | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV54914743, COSV54932079, COSV99624297; called by muse, mutect2, varscan2
- HMGCLL1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778430958, COSV51444918, COSV99232937; called by muse, mutect2, varscan2
- HNF1A | c.1391T>C p.F464S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57463803; called by mutect2, varscan2
- HS3ST6 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765557392, COSV53535551; called by muse, varscan2
- IGSF1 | c.2094A>T p.E698D | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.171); catalogued as COSV63838489; called by muse, mutect2
- KIAA1210 | c.3185A>G p.K1062R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.133); catalogued as COSV68178184, COSV68178202; called by muse, mutect2
- KIF4B | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs778653406, COSV70529956; called by muse, mutect2, varscan2
- L1CAM | c.3289C>T p.R1097W | Missense Mutation (SNP) | VAF 30/295 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs782807254, COSV62828807; called by muse, mutect2, varscan2
- LRRC3B | c.180A>T p.R60S | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as COSV67521713; called by muse, mutect2
- MASP2 | c.1864G>T p.E622* | Nonsense Mutation (SNP) | VAF 23/224 reads (10%) | catalogued as COSV53570406; called by muse, mutect2, varscan2
- MEIS3 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 11/76 reads (14%) | catalogued as rs754981542, COSV58984064; called by muse, mutect2, varscan2
- MGAT4C | c.92T>A p.V31D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV59834413; called by muse, mutect2
- MMP16 | c.248A>C p.N83T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.017); catalogued as COSV54174128; called by muse, mutect2, varscan2
- MTMR10 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV58728836; called by muse, mutect2
- MYLK3 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs780286175, COSV67365112; called by muse, mutect2, varscan2
- MYO1G | c.2381+1G>T p.X794_splice | Splice Site (SNP) | VAF 15/98 reads (15%) | catalogued as COSV51855524; called by muse, mutect2, varscan2
- NOP14 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 33/238 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs143842679; called by muse, mutect2, varscan2
- OR14A16 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.058); catalogued as COSV62926735, COSV62926970; called by muse, mutect2
- OR4C6 | c.180del p.T62Pfs*18 | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs781182602; called by mutect2, pindel
- OR51A7 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs906070592, COSV63788359; called by muse, mutect2, varscan2
- OSMR | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs147223683; called by muse, mutect2, varscan2
- PCDHA3 | c.1451C>T p.A484V | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV63542176, COSV63543299; called by muse, varscan2
- PCYT1B | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63265641; called by muse, mutect2
- PHACTR3 | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV63030496; called by muse, mutect2
- PRDM9 | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as COSV57006794, COSV57014064; called by muse, mutect2, varscan2
- PRICKLE3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781985242, COSV66235061; called by muse, mutect2
- PTCHD4 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59784004; called by muse, mutect2, varscan2
- RASL11A | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV54080614; called by muse, mutect2, varscan2
- RND1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs769890484, COSV59045647; called by muse, mutect2, varscan2
- RNF43 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 23/68 reads (34%) | catalogued as COSV68458952, COSV68459601; called by muse, mutect2, varscan2
- SBF1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs966338815, COSV62368599; called by muse, mutect2, varscan2
- SF3B2 | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV59428945; called by muse, mutect2, varscan2
- SLC7A1 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746536517, COSV66330984; called by muse, mutect2
- SMO | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV50832941; called by muse, mutect2, varscan2
- SOGA3 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64107369; called by muse, mutect2, varscan2
- SRC | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV62440336; called by muse, mutect2, varscan2
- SRGAP1 | c.2662A>G p.S888G | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs375183261; called by muse, mutect2, varscan2
- SYCP2L | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV51654945; called by muse, mutect2, varscan2
- SYNE2 | c.19273G>A p.V6425M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759714086, COSV59956988; called by muse, mutect2, varscan2
- TBC1D8B | c.622C>T p.L208F | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52180569; called by muse, mutect2
- TMEM47 | c.278T>C p.L93P | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52066021; called by muse, mutect2
- TRMT1L | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as COSV62272755; called by muse, mutect2, varscan2
- TSHZ2 | c.2116T>A p.L706M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61589757; called by muse, mutect2, varscan2
- TSKS | c.1244G>T p.G415V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.892); catalogued as COSV55876619; called by muse, mutect2, varscan2
- TTLL2 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs1223233905, COSV53444642; called by muse, mutect2, varscan2
- TTN | c.16930G>T p.A5644S (on ENST00000591111; = p.A4717S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | PolyPhen benign (0.066); catalogued as COSV60169221; called by muse, mutect2, varscan2
- ZBTB20 | c.671G>T p.S224I (on ENST00000474710 / NM_001164342.2; = p.S151I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61856508; called by muse, mutect2, varscan2
- ZKSCAN2 | c.1192A>G p.K398E | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60156731, COSV60157598; called by muse, mutect2
- GPC4 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 13/459 reads (3%) | called by muse, mutect2
- MAP7D3 | c.1844_1851del p.E615Gfs*15 | Frame Shift Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- OR8G2P | c.371T>G p.V124G | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- PTCH2 | c.2850del p.F951Sfs*42 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- TGFBR2 | c.312del p.K105Sfs*19 | Frame Shift Del (DEL) | VAF 24/114 reads (21%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.1120_1121del p.V374Yfs*3 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by pindel, varscan2
- ANOS1 | c.969C>A p.I323= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99391649; called by muse, mutect2, varscan2
- C11orf87 | c.423C>T p.C141= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as rs1397008179, COSV59357394; called by muse, mutect2
- C2CD2 | c.1662G>A p.A554= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs769017798, COSV61599944; called by muse, mutect2, varscan2
- CHRD | c.1347G>A p.E449= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV52609732; called by muse, mutect2, varscan2
- CHRNB2 | c.729C>A p.I243= | Silent (SNP) | VAF 26/241 reads (11%) | catalogued as COSV63808525, COSV63808794; called by muse, mutect2
- COL11A2 | c.3924C>T p.T1308= (on ENST00000341947 / NM_080680.3; = p.T1201= on NM_080679.2) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs753324728, COSV59498939; called by muse, mutect2, varscan2
- COPB2 | c.2532C>T p.P844= | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- DDX39A | c.1227T>C p.N409= | Silent (SNP) | VAF 16/196 reads (8%) | catalogued as COSV54392277; called by muse, mutect2
- FAM47A | c.1413C>T p.P471= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as rs751756215, COSV60498048; called by muse, mutect2, varscan2
- H2BC4 | c.135G>T p.V45= | Silent (SNP) | VAF 26/296 reads (9%) | catalogued as COSV58416769; called by muse, mutect2
- H2BW1 | c.57G>A p.S19= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs371176620, COSV54220693; called by muse, mutect2, varscan2
- HSPA1L | c.1437G>A p.T479= | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as rs532485515, COSV65148795, COSV65149196; called by muse, mutect2, varscan2
- KCNA1 | c.678G>A p.T226= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV66837161; called by muse, mutect2, varscan2
- KDM4B | c.696G>A p.S232= | Silent (SNP) | VAF 51/409 reads (12%) | catalogued as rs200324591; called by muse, mutect2, varscan2
- MCF2L | c.3264C>T p.G1088= (on ENST00000375608; = p.G1056= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1280251093, COSV56179224; called by muse, mutect2
- OR4A5 | c.279A>G p.Q93= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV60521832, COSV60521913; called by mutect2, varscan2
- PCDHA3 | c.2253G>A p.S751= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as rs781829474, COSV63543301; called by muse, mutect2, varscan2
- PLSCR2 | c.495A>G p.R165= (on ENST00000497985 / NM_001199978.1; = p.R92= on NM_020359.2) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV60862378; called by muse, mutect2
- RAB11FIP4 | c.1611C>T p.A537= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV57930583; called by muse, mutect2, varscan2
- RGN | c.357T>C p.A119= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV60276493; called by muse, mutect2
- RNF19A | c.126A>T p.R42= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV61993870; called by muse, mutect2, varscan2
- SFN | c.228G>A p.E76= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV59432930; called by muse, mutect2, varscan2
- SIK3 | c.2022C>A p.I674= (on ENST00000445177 / NM_001366686.2; = p.I632= on NM_025164.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/195 reads (13%) | catalogued as COSV52617965; called by muse, mutect2, varscan2
- SLITRK2 | c.49T>C p.L17= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV59426833; called by muse, mutect2
- TBL1X | c.135G>A p.S45= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as rs771607809; called by mutect2, varscan2
- TTN | c.8430C>T p.A2810= (on ENST00000591111; = p.A2764= on NM_003319.4) | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV60169232; called by muse, mutect2
- UGT2B17 | c.864C>T p.P288= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs1409592667, COSV100497334; called by muse, mutect2, varscan2
- UVSSA | c.1380G>A p.A460= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs1057057610, COSV66230248; called by muse, mutect2, varscan2
- ZNF274 | c.1209T>C p.R403= (on ENST00000610905; = p.R298= on NM_016324.3) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV58765351; called by muse, mutect2
- ZNF569 | c.1773T>G p.T591= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as COSV57596779; called by muse, mutect2, varscan2
- ZNF668 | c.1032G>A p.T344= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV56216172; called by muse, mutect2, varscan2
- C3P1 | n.3077G>A | RNA (SNP) | VAF 35/211 reads (17%) | catalogued as rs563514269; called by muse, mutect2, varscan2
- ELK1 | chrX:47650500 C>A | 5'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99902429; called by muse, mutect2, varscan2
- KHDC4 | c.1266+1444G>A | Intron (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100850865; called by muse, mutect2, varscan2
- OR2W5 | n.765C>T | RNA (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- RBM46 | c.*1A>C | 3'UTR (SNP) | VAF 13/113 reads (12%) | catalogued as COSV55977017, COSV99908516; called by muse, mutect2
